Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25K, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25K-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS -----

1) RIGHT PARATHYROID (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

2) THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

ICB-0-3

TUMOR SITE:

Right lobe

Left lobe

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

HISTOLOGIC TYPE:

Papillary carcinoma

hw
5/4/11

TUMOR SIZE:

2.5 cm

FOCALITY:

Multifocal

LYMPH NODES:

Metastatic carcinoma in 3 of 11 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT2: Tumor >2 cm but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Nodular hyperplasia

Focal lymphocytic thyroiditis.

[page 2 of 2]
PART #2: RIGHT TOTAL THYROID & CENTRAL NECK
Dictated:

The specimen is received fresh labeled with the patient's name xxxx and is designated right total thyroid and central neck. The specimen consists of a grossly recognizable total thyroidectomy with a small amount of central fibrofatty soft tissue weighing a total of 15.6 grams and measuring 6.5 x 5.1 x 1.8 cm. The specimen comes oriented with a long black stitch designating per surgeon of right thyroid tumor. This specimen left lobe is noted to be 3.9 x 2.5 x 1.3 cm and the right lobe is noted to be 5.1 x 3.5 x 1.8 cm. Prominent vasculature is noted over the right lobe. However, the specimen is intact and the capsule is not excised. The anterior aspect of the specimen is inked orange. Posterior aspect of the specimen is inked black. The specimen is serially sectioned from right superior pole to right inferior pole to reveal a 2.5 x 2.5 x 1.8 cm well circumscribed brittle soft tan nodule located in the right middle to right inferior pole of the right lobe. A portion of the specimen is submitted for tissue banking. The remaining right lobe is submitted in its entirety in blocks A - H with nodules submitted in blocks D - H. The isthmus is serially sectioned to reveal no masses or lesions. The left inferior lobe is serially sectioned from inferior to superior to reveal tan homogeneous parenchyma. No masses or lesions are identified. The remaining portion of the thyroid is submitted its entirety. The associated fibroadipose tissue as previously mentioned was extensively sampled to reveal no possible lymph nodes. The associated soft tissue is submitted in its entirety in block O. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

- 1 - A - 1 RIGHT SUPERIOR POLE
- 1 - B - 2
- 1 - C - 1
- 4 - D - G - 1/EACH NODULE EACH
- 1 - H - 1 RIGHT INFERIOR POLE
- 1 - I - 2 ISTHMUS
- 1 - J - 1 LEFT INFERIOR POLE
- 3 - K - N - 3/EACH
- 1 - M - 1 LEFT SUPERIOR
- 1 - O - M FAT
- 15 - TOTAL - M

Source: NCI Genomic Data Commons file 4ae3f766-53be-4784-8197-c8c125887cd0 (TCGA-ET-A25K.2BBDC29D-287A-4275-8B15-C2074EEA1243.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).